Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A68A, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A68A-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 3
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Patient with pheochromocytoma. Operative Procedure/Tissue Submitted: Left adrenalectomy - possible left nephrectomy, distal pancreatectomy and splenectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Left adrenal gland and periadrenal tissue. Short stitch lateral. Short stitch superior. Two long stitch anterior." Received in formalin in a large container is a 240 gram, 11.4 x 6.6 x 5.3 cm resection specimen oriented with long stitch representing lateral, and two short stitches representing superior, and long stitches representing anterior. There is a 6.9 x 6.6 x 3.5 cm fully encapsulated mass with a 3.0 x 2.7 x 2.6 cm attached nodule at the superior pole of the mass and a 1.9 cm long x 1.6 cm wide soft tissue pedicle at the superior end of the specimen. Specimen is inked black. This specimen is serially sectioned revealing that the superior end of the specimen contains unremarkable adrenal glands. The smaller nodule which consists of a pale tan solid cut surfaces appears to be emanating from the medulla of the native adrenal gland. The larger nodule contains heterogeneous cut surfaces with mottled yellow dark brown at the periphery and cystic degeneration towards the center. The two nodules abut each other and appear to be separated by a

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 4
SEX: F

ACCESSION

OPER DATE:

REQ DOC:

possible thin capsule.

- 1A. Superior tip of specimen, possible margin of soft tissue.
- 1B. Smaller nodule emanating from adrenal glands.
- 1C. Junction of smaller nodule to the larger nodule (anterior aspect).
- 1D. Anterior-lateral aspect of larger mass (superior half).
- 1E. Representative medial-inferior half of larger nodule.
- 1F-I. Representative capsule from larger adrenal mass.
- 1J-K. Representative sections of capsule from smaller adrenal mass.
2. "Periaortic tissue." Received in formalin in a small container is a 3.1 x 2.1 x 0.5 cm fragment of soft tissue. This specimen is serially sectioned revealing pale tan, solid cut surfaces extending to approximately 50% of the edge.
- 2A & 1B. Entirely submitted.

PROCEDURE: SPDX

VERIFIED BY:

1. Left adrenal gland, adrenalectomy: Pheochromocytoma, consisting of two adjacent masses (6.9 cm and 3.0 cm). No lymphovascular invasion identified. See comment.

2. Soft tissue, periaortic, excision: Ganglion and nerve. No tumor or lymph nodes identified.

COMMENT:

This adrenal resection contains two masses that appear to be adjacent and confined to the gland. Histologically, the nodules are both pheochromocytomas, but have subtly different morphologies. Given the patient's young age and the recent diagnosis of medullary thyroid carcinoma, a syndromic form is likely. Given these considerations, two discrete tumors is favored.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

HIVAA Discrepancy		/

Source: NCI Genomic Data Commons file 72938817-5445-4cc9-ad28-6d2269fb2934 (TCGA-RW-A68A.9833AC9F-D963-4F71-9894-DCEED94D1903.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).